Surgical pathology report (de-identified scan), TCGA case TCGA-4H-AAAK, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Proteogenex, Inc., specimen TCGA-4H-AAAK-01A (Primary Tumor).

Age/Sex: years / F

Date:

Procedure: Left radical mastectomy

Preoperative diagnosis: CARCINOMA OF THE LEFT BREAST

Postoperative diagnosis: SEE MICROSCOPIC DIAGNOSIS BELOW

Specimen(s): 1. LEFT BREAST 2. LEFT AXILLARY CONTENTS

Diagnosis:

1. LEFT BREAST:

- Infiltrating lobular carcinoma grade 2
- Tumor is 2.8 x 3.5 x 3.0 cm in dimensions
- Vascular invasion is not present

ICD-6-3
Carcinoma Lobular infiltrating NOS 8520/3
Site: B Breast NOS
C50.9
Qx 5/21/14

2. LEFT AXILLARY LYMPH NODES:

- Four (out of fourteen) axillary lymph nodes are positive for metastatic carcinoma

Gross description:

1. LEFT BREAST:

Received fresh, is a left breast measured 30.0 x 27.0 x 9.0 cm in dimensions with an axillary fat, en bloc. The firm white-gray tumor 2.8 x 3.5 x 3.0 cm in dimensions is present in the outer quadrants.

2. LEFT AXILLARY CONTENTS:

Within the axillary fat there are fourteen lymph nodes ranging from 0.2 to 2.0 cm in greatest dimension.

Source: NCI Genomic Data Commons file 36d147aa-749c-46d8-994e-98c61058994c (TCGA-4H-AAAK.8894688F-7167-48A1-BB1B-FC219B7675C2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).